Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8630, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8630-01A (Primary Tumor).

Final Diagnosis

Right kidney, partial nephrectomy (with frozen section):

Papillary renal cell carcinoma.

Fuhrman grade 3.

Tumor size: 4.5 cm in greatest dimension.

No angiolymphatic invasion.

No capsular invasion.

Margin is free of tumor.

AJCC pathologic staging data: pT1b, NX.

Right kidney margin:

Negative for malignancy.

Clinical Information

Right lower lobe renal mass.

Frozen Section Diagnosis

FSA, Right partial nephrectomy – 6 x 5 x 4.5 cm segment of kidney, capsule intact. Margin inked black and capsule orange. Sections show 4.5 x 4.5 x 4.0 cm yellow-red mass focally to within 0.2 cm of inked margin, sampled as FSA. Portion obtained for EXPO study and remainder for permanents. Margins free

Gross Description

"NFSA." Received after frozen section is a 53 gram, 6.0 x 5.0 x 4.5 cm segment of kidney. The resection margin has been previously inked black and the capsule has been previously inked orange. The specimen has been previously sectioned to reveal a 4.5 x 4.5 x 4.0 cm yellow-red friable mass. The mass grossly appears to come to within 0.2 cm of the inked margin at frozen section. A portion of the specimen has been submitted for frozen section in cassette "FSA,". "A1-A2," mass to include resection margin; "A3," mass to include capsule.

"B, Right kidney margin." Received are 3 kidney tissue fragments which are less than 1 gram and range from 0.9 to 1.5 cm in greatest dimension. All of the tissue fragments will be inked black and submitted in toto. "B," all

Source: NCI Genomic Data Commons file a8d8978d-fd00-4394-8c2b-f39b8904e53a (TCGA-A4-8630.50FF6EE3-E04A-40DB-A47B-4A62B5EADADB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).